Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A6S8, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A6S8-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

oligodendroglioma, anaplastic (Grade III)

9451/3

Path Site: brain, frontal C 71.1

COCF Site: brain, supratentorial C 71.0

fw
4/2/14

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: F Acct: Reported:
Physician(s):
Phy Location:

Clinical History

-year-old woman experiences memory problems and confusion . On imaging, there is a right frontal complex heterogeneous mass with zones of necrosis and cyst formation, with hemorrhagic nodular enhancing areas. The lesion involves the corpus callosum and extends into the left parietal and temporal lobes

across the corpus callosum.

Operative Diagnoses

Right frontal brain tumor

Operation / Specimen

A: Brain, right frontal tumor, biopsy

Pathologic Diagnosis

Brain, right frontal, excisional biopsy: Anaplastic oligodendroglioma (WHO 3).

1p, 19q LOH (codeletion): Positive.

MGMT: Positive.

MIB-1 proliferation index: 18%.

See Microscopy Description and Comment.

Comment

The sections contain portions of a rather cellular glial neoplastic proliferation that has an oligodendroglial phenotype.

The neoplastic cells are rather uniformly round, with a borderline mitotic rate of 3% / ten high power fields, and an

elevated MIB-1 proliferation index of 18% in the more active areas. The tumor has focal microvascular proliferation,

but is devoid of tumor necrosis. There are also zones of sparse cellularity with microcalcifications.

The neoplasm is a cellular oligodendroglioma with 1p, 19q LOH codeletion, positive IDH1, a modest mitotic rate,

positive MGMT, and a high proliferation index. The biopsy is somewhat small, contains tumor at the low end of

anaplastic transformation, and is probably not representative of the anaplastic regions depicted on the imaging

studies

The morphological features in this sample may be correlated with clinical, imaging, and operative findings for their

interpretation and patient's follow up.

Electronically Signed Out

M.D., Senior Staff Pathologist

Surgical Pathology

Page 2 of 3

Consultant: MD, Senior Staff Pathologist

Procedures/Addenda

MGMT Promoter Methylation

[page 2 of 3]
Date Ordered: **Date Reported:**

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A1).

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: **Date Reported:**

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is detected.

Informative loci are: D1S548, D1S1592, D1S552, D19S412

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A1). DNA extracted from a

corresponding blood specimen was used as a normal reference control. D19S219, PLA2G4C, D19S606 and

D19S1182 loci are not informative. Histologic correlation is necessary.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

Surgical Pathology

Page 3 of 3

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

[page 3 of 3]
otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

M.D., Senior Staff Pathologist

Intra-Operative Consultation

A.

Brain, right frontal tumor, biopsy: Gliofibrillary neoplasm, possibly high histological grade (C/W

oligodendroglioma;

R/O other). Touch preparation smears performed at and results

reported to the

Physician of Record.

M.D., Senior

Staff Pathologist

Gross Description

A.

"Right frontal brain tumor", received fresh, one fragment, 1.4 cm across. Semi firm, focally necrotic and hemorrhagic, and glistening greyish-pink. In total, A1.

Microscopic Description

IMMUNOHISTOCHEMISTRY: The neoplastic cells are IDH1 positive. There is focal microvascular cellular proliferation demonstrable with the CD34. There is only sparse perivascular microglia made evident with the CD163.

With the MIB-1 there is a proliferation index of 18% in frequent more active areas.

ICD-9(s): 191.9 191.9

Billing Fee Code(s): A:

LOH 1p19q:

MGMT:

Source: NCI Genomic Data Commons file 3996f1bb-b1ed-49cf-83cc-b11dca6892da (TCGA-DU-A6S8.CCEA4518-483F-48A1-92C5-811EC8B66256.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).